Gene-level copy-number profile of tumor specimen ALCH-ADUZ-TTP1-A from ALCHEMIST case ALCH-ADUZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 61.8 years (22,585 days).
Specimen ALCH-ADUZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e68feda-209e-4306-82aa-2bb4d2844a6f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADUZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/0cf03408-5b6f-4d8a-b405-8059d205d902

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 108; copy number 1: 24,261; copy number 2: 29,578; copy number 3: 4,384; copy number 4: 59; copy number 10: 1; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:42,915,989–42,925,838, 1 gene: PTCRA.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr10:49,771,841–49,773,299, 1 gene: MAPK6P6.
- chr10:132,181,225–132,205,759, 2 genes (within-gene range 0–1): AL512622.1, DPYSL4.
- chr15:20,228,620–21,951,323, 86 genes (broad region; genes not listed).
- chr15:58,815,272–58,817,728, 1 gene (within-gene range 0–1): AC090515.5.
- chr22:41,922,032–41,947,152, 3 genes: TNFRSF13C, MIR378I, CENPM.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:178,406,695–179,465,305, 4 genes, copy number 10–12: RNA5SP173, AC017087.1, AC018710.1, AC020551.1.
- chr15:21,980,277–21,981,245, 1 gene, copy number 12: OR11J6P.

Autosomal genes at a single copy (total copy number 1): 23,839. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
